Somatic mutation profile of tumor specimen 0DWGJI from CCDI case PBCNRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (482 days).
Specimen 0DWGJI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e163268-e6c7-4151-93a3-afc2e01ee33a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ac0af40-068b-4809-9957-240fb4c4e2f8

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 73/87 reads (84%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NACC2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs1192910616; called by muse, mutect2, varscan2
- HSPA12B | c.2001C>T p.T667= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs1156745689, COSV53925246; called by mutect2, varscan2
- DMTN | c.*52T>A | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
